Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3ZP, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3ZP-01A (Primary Tumor).

[page 1 of 3]
	Yes	No

Surgical Pathology Report

Tel

DOB
Physician

Collected:

Accession:

Received:

Case type: Surgical Case

ICD-0-3

DIAGNOSIS

(A) PAROTID LYMPH NODE:

Lymph node, no tumor present (0/1)

(B) RIGHT NECK DISSECTION, LEVEL II A:

METASTATIC PAPILLARY THYROID CARCINOMA IN LYMPH NODE (1/8)

(C) RIGHT NECK DISSECTION, LEVEL II B:

Lymph nodes, no tumor present (0/8)

(D) RIGHT NECK DISSECTION, LEVEL III:

METASTATIC PAPILLARY THYROID CARCINOMA IN LYMPH NODES AND SOFT TISSUE (1/5)

(E) RIGHT NECK DISSECTION, LEVEL IV:

Lymph nodes, no tumor present (0/15)

(F) RIGHT ANTERIOR NECK:

Fibrous tissue, no tumor present

(G) RULE OUT PARATHYROID:

METASTATIC PAPILLARY THYROID CARCINOMA IN LYMPH NODE (1/1), no parathyroid present

(H) RULE OUT INFERIOR PARATHYROID:

Skeletal muscle and adipose tissue, no tumor present, no parathyroid present

(I) RIGHT PARATRACHEAL LYMPH NODES:

METASTATIC PAPILLARY THYROID CARCINOMA IN LYMPH NODE (1/1)

(J) RIGHT SUPERIOR PARATHYROID:

METASTATIC PAPILLARY THYROID CARCINOMA IN LYMPH NODE (1/1), no parathyroid present

(K) LEFT PARATRACHEAL LYMPH NODES:

Lymph nodes, no tumor present (0/3), parathyroid gland

(L) TOTAL THYROID:

PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE WITH AREAS OF POOR DIFFERENTIATION

Location: Right lobe

Multi-focal: No

Size = 2.6 cm

Extrathyroidal extension: Present, extending into fibroadipose tissue

Lymphovascular invasion: Present

Resection Margins: Positive

Background Thyroid: Chronic lymphocytic thyroiditis

(M) RIGHT UPPER MEDIASTINAL LYMPH NODES:

METASTATIC PAPILLARY THYROID CARCINOMA IN LYMPH NODES (4/7),

Extranodal extension: Present

parathyroid gland

[page 2 of 3]
Surgical Pathology Report

DOB:
Physician:

Collected:
Received:

Pathologist:
Case type: Surgical Case

Accession:

GROSS DESCRIPTION

(A) PAROTID LYMPH NODE - A 1.0 x 0.5 x 0.4 cm yellow piece of fatty tissue containing a 0.6 cm diameter lymph node. Specimen submitted entirely in A.

(B) RIGHT NECK DISSECTION, LEVEL II A - A fragment of tan-red, soft tissue measuring 2.0 x 2.0 x 1.0 cm. Multiple lymph nodes are separated from fat and submitted.

SECTION CODE: B1, five lymph nodes; B2, one lymph node, bisected; B3, one lymph node, bisected; B4, one lymph node, bisected.

(C) RIGHT NECK DISSECTION, LEVEL II B - A fragment of tan-red, soft tissue measuring 2.0 x 1.0 x 1.0 cm. Lymph nodes are separated from fat and submitted.

SECTION CODE: C1, C2, multiple lymph nodes.

(D) RIGHT NECK DISSECTION, LEVEL III - A fragment of tan-red, soft tissue measuring 4.0 x 1.5 x 1.0 cm. Lymph nodes are separated from fat and submitted.

SECTION CODE: D1, one lymph node, bisected; D2, one lymph node, bisected; D3, three lymph nodes; D4, multiple smaller lymph nodes.

(E) RIGHT NECK DISSECTION, LEVEL IV - A fragment of tan-red, soft tissue measuring 1.0 x 1.0 x 2.0 cm. Lymph nodes are separated from fat and submitted.

SECTION CODE: E1-E3, multiple lymph nodes.

(F) RIGHT ANTERIOR NECK - A fragment of tan-red, soft tissue measuring 4.0 x 2.0 x 0.8 cm.

SECTION CODE: F1, F2, lymph nodes.

(G) RULE OUT PARATHYROID - A piece of tan-pink soft tissue (0.3 x 0.3 x 0.2 cm, 0.008 grams), submitted entirely in FSG1 for frozen section diagnosis. Touch prep was performed.

*FS/DX: ONE LYMPH NODE, INVOLVED BY METASTATIC PAPILLARY THYROID CARCINOMA.

(H) RULE OUT INFERIOR PARATHYROID - A tan-yellow piece of soft tissue (1.2 x 0.5 x 0.2 cm, 0.3 grams), submitted entirely in FSH1 for frozen section diagnosis. Touch prep was also performed.

*FS/DX: FATTY TISSUE, BLOOD VESSELS, AND SKELETAL MUSCLE; NO TUMOR PRESENT.

(I) RIGHT PARATRACHEAL LYMPH NODES - One fragment of tan-red, soft tissue, measuring 1.0 x 0.8 x 0.5 cm. One lymph node is separated and submitted after bivalving.

SECTION CODE: I, one lymph node.

(J) RIGHT SUPERIOR PARATHYROID - A well-circumscribed, white-tan soft tissue, 0.7 x 0.4 x 0.3 cm and 0.001 gram, entirely submitted in J. a

(K) LEFT PARATRACHEAL LYMPH NODES- Fibroadipose tissue, 1.5 x 1.5 x 0.8 cm. Four lymph nodes are identified, ranging from 0.3 x 0.3 x 0.2 cm to 0.8 x 0.4 x 0.2 cm, entirely submitted in K.

(L) TOTAL THYROID - The specimen consists of a thyroid (7.5 x 5.0 x 2.5 cm). The right lobe of the thyroid is distorted by a grossly palpable nodule located in the mid anterior portion of the right lobe.

There is a 2.6 x 2.1 x 1.2 cm poorly circumscribed tumor, which grossly involves the anterior capsule and is located approximately 0.3 cm from the posterior margin. The left lobe and the isthmus are grossly unremarkable.

SECTION CODE: L1-L11, right lobe from the superior aspect towards the anterior aspect (L3, L5, L7, L9 are the () portion of the right lobe; L4, L6, L8 and L10 are the () portion of the right lobe); L12, L13, isthmus, submitted entirely; L14-L16, representative sections of the left lobe, submitted from superior towards inferior aspect.

(M) RIGHT UPPER MEDIASTINAL LYMPH NODES - Fibroadipose tissue, 2.0 x 2.0 x 0.8 cm in aggregate. Eight lymph nodes are identified, ranging from 0.1 x 0.1 x 0.1 to 0.5 x 0.4 x 0.3 cm.

SECTION CODE: M1, two lymph nodes; M2, three lymph nodes; M3, three lymph nodes.

CLINICAL HISTORY

Surgical Pathology Report		Page 2 of 3
File under: Pathology		

[page 3 of 3]
Surgical Pathology Report

Physician: _____

Collected: _____

Pathologist: _____

Accession: _____

Received: _____

Case type: Surgical Case

Papillary thyroid cancer.

SNOMED CODES

T-B6000, M-80503, M-B0630,

"Some tests reported here may have been developed and performance characteristics determined by approved by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or

Entire report and diagnosis completed by: _____

Surgical Pathology Report		Page 3 of 3
File under: Pathology		

Source: NCI Genomic Data Commons file 75d3f66a-fd53-4913-a125-89fbdf56bfe7 (TCGA-EL-A3ZP.8035BE61-91DD-41FB-ABC8-77BE24327645.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).